CCDI case PBCBTF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/1bb1224a-8af4-4e6b-bd73-c24da6c65dd6

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.8 years (1,397 days).

Biospecimens (3 samples)
- Sample 0DNJA8: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DNJAX: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DNJBN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
